Somatic mutation profile of cancer-model specimen HCM-SANG-0285-C18-85A (3D Organoid; aliquot HCM-SANG-0285-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0285-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0285-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81120fca-7079-4ede-b0c5-2bf07f5772a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0285-C18-10B (Blood Derived Normal), aliquot HCM-SANG-0285-C18-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e993165-5763-412c-ac01-f8f0a44ec49f

The open-access MAF lists 333 somatic variants for this specimen: 248 protein-altering or splice-affecting, 73 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Silent 73, Nonsense Mutation 18, Intron 7, Frame Shift Ins 5, RNA 3, Frame Shift Del 2, 3'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3454C>T p.Q1152* | Nonsense Mutation (SNP) | VAF 111/233 reads (48%) | catalogued as rs1064795228, CM970087, COSV57345291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 150/365 reads (41%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/285 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA1 | c.2683C>T p.Q895* | Nonsense Mutation (SNP) | VAF 144/322 reads (45%) | catalogued as rs397508997, CM020400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSCAM | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs1419539530, COSV68029589; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 195/383 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 196/198 reads (99%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- SMAD3 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 116/207 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906850, CM110722, COSV59286247; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADGRB1 | c.2251G>A p.V751I | Missense Mutation (SNP) | VAF 536/717 reads (75%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.708); catalogued as rs977693674, COSV100029352; called by muse, mutect2, varscan2
- AGO1 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 159/335 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV64596396; called by muse, mutect2, varscan2
- AMH | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 272/538 reads (51%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs369849113; called by muse, mutect2, varscan2
- ARHGEF1 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 73/445 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs369952369; called by muse, mutect2, varscan2
- ARHGEF28 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 191/396 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs779778189; called by muse, mutect2, varscan2
- ASMT | c.823C>G p.P275A (on ENST00000381229; = p.P303A on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/340 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as rs760913251; called by muse, mutect2, varscan2
- AXIN1 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 117/524 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs546827136, COSV99249382; called by muse, mutect2, varscan2
- BACH2 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 280/447 reads (63%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs760300804, COSV57595293; called by muse, mutect2, varscan2
- BATF2 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367686912; called by muse, mutect2
- C19orf84 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 277/539 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1267921697, COSV55740361; called by muse, mutect2, varscan2
- CAMK4 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 190/388 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV56663111; called by muse, varscan2
- CASP10 | c.806G>A p.S269N | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as rs1277938751; called by muse, mutect2, varscan2
- CDH11 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs185190786, COSV51763570; called by muse, mutect2, varscan2
- CDH18 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 161/317 reads (51%) | catalogued as rs762348492, COSV56922945, COSV99937365; called by muse, mutect2, varscan2
- CENPU | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 124/246 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV55658194; called by muse, mutect2, varscan2
- CFTR | c.1642C>G p.L548V | Missense Mutation (SNP) | VAF 146/282 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CD941999; called by muse, mutect2, varscan2
- CHD7 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs1014640333; called by muse, mutect2, varscan2
- CHRM2 | c.1018A>C p.T340P | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV57770184, COSV57778914; called by muse, mutect2
- COL1A2 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51952943, COSV51957864; called by muse, mutect2, varscan2
- COL24A1 | c.2944A>C p.S982R | Missense Mutation (SNP) | VAF 111/246 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV65309667; called by muse, mutect2, varscan2
- CR2 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 320/456 reads (70%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs755984980, COSV65509255; called by muse, mutect2, varscan2
- CSMD3 | c.9379C>T p.R3127* (on ENST00000297405 / NM_001363185.1; = p.R2958* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 102/507 reads (20%) | catalogued as COSV52211222; called by muse, mutect2, varscan2
- CTNND2 | c.1228T>G p.L410V | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV58861735, COSV58895397; called by muse, mutect2
- CYYR1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 35/394 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV54832373, COSV54839783; called by muse, mutect2
- DCAF12L2 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 535/535 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482133858, COSV63582727; called by muse, mutect2, varscan2
- DHRS7C | c.796G>A p.V266M (on ENST00000330255 / NM_001220493.2; = p.V265M on NM_001105571.3) | Missense Mutation (SNP) | VAF 251/514 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs774255168, COSV57651134; called by muse, mutect2, varscan2
- DNAH11 | c.3246C>A p.F1082L | Missense Mutation (SNP) | VAF 220/445 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323011072; called by muse, mutect2, varscan2
- DNAH2 | c.11588G>A p.R3863H | Missense Mutation (SNP) | VAF 75/589 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs772517065, COSV66720564; called by muse, varscan2
- DPH1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 22/433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746958259, COSV53983551; ClinVar: uncertain significance; called by muse, mutect2
- ELFN1 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 47/910 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs549714789; called by muse, mutect2
- EPB41L3 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 101/311 reads (32%) | catalogued as rs1283679414, COSV100549552; called by muse, mutect2, varscan2
- EPHB6 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 460/828 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs756659047, COSV67417355, COSV67421793; called by muse, mutect2, varscan2
- EYS | c.808T>G p.C270G | Missense Mutation (SNP) | VAF 153/286 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV60978722, COSV60987743; called by muse, mutect2, varscan2
- FAM83H | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 361/1564 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs1364347682; called by muse, mutect2, varscan2
- FAT3 | c.5759A>G p.Y1920C | Missense Mutation (SNP) | VAF 133/275 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1390513626; called by muse, mutect2, varscan2
- FAT4 | c.10420A>C p.T3474P | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV58677374, COSV58681090; called by muse, mutect2, varscan2
- FBF1 | c.1937G>A p.R646Q (on ENST00000586717; = p.R660Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 189/423 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs935636616; called by muse, mutect2, varscan2
- FCAR | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs374350579; called by muse, mutect2, varscan2
- FCGR2B | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 546/782 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV52682470; called by muse, mutect2, varscan2
- FERD3L | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 194/466 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51761976, COSV51764624; called by muse, mutect2, varscan2
- FGFBP3 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 83/626 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs778883939; called by muse, varscan2
- FLG2 | c.3312A>C p.Q1104H | Missense Mutation (SNP) | VAF 64/949 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV66171387; called by muse, mutect2
- FREM2 | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 25/495 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54826828, COSV54842467; called by muse, mutect2
- GABPA | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 133/304 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs2829897; called by muse, mutect2, varscan2
- GATA5 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 536/886 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782614097; called by muse, mutect2
- GNB1L | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 283/581 reads (49%) | catalogued as COSV61547532; called by muse, mutect2, varscan2
- GNB3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 376/545 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs150593798; called by muse, mutect2, varscan2
- GRM6 | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 164/343 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs369642678; ClinVar: uncertain significance; called by muse, mutect2
- GSG1L | c.965G>A p.R322Q (on ENST00000447459 / NM_001109763.2; = p.R167Q on NM_144675.2) | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs577887323, COSV66580450; called by muse, mutect2, varscan2
- GUCY1B1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV52378565; called by muse, mutect2, varscan2
- HDAC5 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 160/352 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.277); catalogued as rs951329331; called by muse, mutect2, varscan2
- HOXD4 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 263/497 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs758609539; called by muse, mutect2, varscan2
- HS6ST3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 203/474 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV65009962; called by muse, mutect2, varscan2
- HSPG2 | c.7960G>A p.A2654T | Missense Mutation (SNP) | VAF 213/470 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.067); catalogued as rs139645957; called by muse, mutect2, varscan2
- HTR3E | c.464C>T p.P155L (on ENST00000415389 / NM_001256613.1; = p.P170L on NM_182589.2) | Missense Mutation (SNP) | VAF 165/411 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs768726496; called by muse, mutect2, varscan2
- JAG2 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 269/549 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.536); catalogued as rs1011982956; called by muse, mutect2, varscan2
- KALRN | c.3793C>T p.R1265W | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025185719, COSV53761583; called by muse, mutect2, varscan2
- KCNH8 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376188228; called by muse, mutect2, varscan2
- KDM5A | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 51/559 reads (9%) | catalogued as rs1267802668, COSV66991735; called by muse, mutect2
- KLHL30 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 89/525 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767478070; called by muse, mutect2, varscan2
- KRTAP4-2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 359/723 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs754307555, COSV66658212; called by muse, mutect2, varscan2
- L34079.1 | c.35C>T p.T12M | Missense Mutation (SNP) | VAF 46/605 reads (8%) | SIFT deleterious, low confidence (0); catalogued as rs765619391; called by muse, mutect2
- LARGE2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 187/408 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs533759355; called by muse, mutect2, varscan2
- LMX1A | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 555/789 reads (70%) | SIFT tolerated (0.73); PolyPhen benign (0.033); catalogued as COSV54216821; called by muse, mutect2, varscan2
- LRRK1 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 172/392 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs761695009, COSV99444319; called by muse, mutect2, varscan2
- LYPD3 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 202/436 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs763349237, COSV54988221; called by muse, mutect2, varscan2
- MACF1 | c.12601C>T p.R4201W (on ENST00000372915; = p.R2134W on NM_012090.5) | Missense Mutation (SNP) | VAF 183/346 reads (53%) | catalogued as rs374316302; called by muse, mutect2, varscan2
- MACROD2 | c.1045G>A p.V349M (on ENST00000642719; = p.V321M on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.674); catalogued as rs1462177900; called by muse, mutect2
- MAGEB5 | c.289T>G p.L97V | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.457); catalogued as COSV66868829; called by muse, mutect2, varscan2
- MAST2 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 157/301 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs776195513, COSV100787750; called by muse, mutect2, varscan2
- MEGF10 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as rs568794084, COSV57245707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEGF8 | c.2624G>A p.R875H (on ENST00000251268 / NM_001271938.2; = p.R808H on NM_001410.3) | Missense Mutation (SNP) | VAF 207/478 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149768800; called by muse, mutect2, varscan2
- MIA3 | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as rs754576217; called by muse, mutect2, varscan2
- MLC1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs74315275, CM113858, COSV61117916; called by muse, mutect2, varscan2
- MSR1 | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 190/379 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV50529985; called by muse, mutect2, varscan2
- MUC12 | c.2666C>T p.P889L (on ENST00000379442; = p.P746L on NM_001164462.1) | Missense Mutation (SNP) | VAF 236/1554 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.722); catalogued as rs753399597; called by muse, mutect2, varscan2
- MXRA5 | c.6422G>A p.R2141H | Missense Mutation (SNP) | VAF 20/606 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs971233635, COSV54248850; called by muse, mutect2
- MXRA8 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 214/451 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769804902; called by muse, mutect2, varscan2
- MYO1H | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 218/621 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs548092851, COSV60448675; called by muse, mutect2, varscan2
- NAALADL2 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs747922150; called by muse, mutect2
- NAGPA | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 219/480 reads (46%) | PolyPhen probably damaging (0.91); catalogued as rs1313101051, COSV56570674; called by muse, mutect2, varscan2
- NEURL3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 327/668 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1223745562; called by muse, mutect2, varscan2
- NLGN3 | c.1356G>C p.E452D (on ENST00000358741 / NM_181303.2; = p.E432D on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/394 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as COSV62441416; called by muse, mutect2, varscan2
- NUAK1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 297/488 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772183684, COSV54605730; called by muse, mutect2, varscan2
- NYAP2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 157/332 reads (47%) | catalogued as COSV56013284, COSV56015077; called by muse, mutect2, varscan2
- OLFM3 | c.704G>C p.G235A (on ENST00000338858 / NM_001288821.1; = p.G215A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/369 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58803568, COSV58803760; called by muse, mutect2, varscan2
- OR2T8 | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 36/670 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60661805; called by muse, mutect2
- OVCH2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs550450830, COSV71953002; called by muse, mutect2, varscan2
- OXR1 | c.1373C>T p.S458L (on ENST00000442977 / NM_001198532.1; = p.S457L on NM_018002.3) | Missense Mutation (SNP) | VAF 144/538 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as rs759832362, COSV56324030; called by muse, varscan2
- PDZRN4 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV68413867; called by muse, mutect2, varscan2
- PHOX2A | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 179/387 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV53352998; called by muse, mutect2, varscan2
- PLCH2 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 346/725 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.831); catalogued as rs751360942; called by muse, mutect2, varscan2
- PLD3 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 149/338 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as rs1325388394, COSV100735251; called by muse, mutect2, varscan2
- PLD4 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 254/530 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as rs1324439385; called by muse, mutect2
- POU3F3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.522); catalogued as rs1214766342; called by muse, varscan2
- PRAMEF12 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 37/401 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63215590; called by muse, mutect2
- PRAMEF2 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1063787, COSV53576618; called by muse, mutect2, varscan2
- PRDM14 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 262/528 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1224885523; called by muse, mutect2, varscan2
- PXDN | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 193/388 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779177065, COSV53241473; called by muse, mutect2, varscan2
- RALGPS1 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 231/284 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52230930; called by muse, mutect2, varscan2
- RASA1 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 156/372 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.417); catalogued as rs377099473; called by muse, mutect2, varscan2
- RBM4B | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 250/515 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs760376120; called by muse, mutect2, varscan2
- REXO1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 298/669 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.296); catalogued as rs760852630; called by muse, mutect2, varscan2
- RGS12 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 192/396 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs779402258, COSV60907852; called by muse, mutect2, varscan2
- SASH1 | c.3179G>C p.W1060S | Missense Mutation (SNP) | VAF 375/620 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.963); catalogued as rs750455930, COSV66567696; called by muse, mutect2, varscan2
- SDK2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 179/411 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1226068652; called by muse, mutect2, varscan2
- SH2D7 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs373029841; called by muse, mutect2, varscan2
- SLC40A1 | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 151/322 reads (47%) | catalogued as COSV53724048; called by muse, mutect2, varscan2
- SLC6A5 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 245/523 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs1460494669; called by muse, mutect2, varscan2
- SLIT1 | c.2563G>A p.V855M | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs765149937; called by muse, mutect2, varscan2
- SMAD3 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 142/329 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100529000; called by mutect2, varscan2
- SNX24 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 32/472 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs769236921; called by muse, mutect2
- SPNS2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 223/503 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs746565744, COSV61230040; called by muse, mutect2, varscan2
- SYNE1 | c.24485A>C p.K8162T (on ENST00000367255 / NM_182961.4; = p.K8091T on NM_033071.3) | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV54911117, COSV54968317; called by muse, mutect2
- TAFA1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 138/277 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1055625351, COSV72037141; called by muse, mutect2, varscan2
- TCF12 | c.1636C>T p.Q546* | Nonsense Mutation (SNP) | VAF 120/300 reads (40%) | catalogued as rs1277753045; called by muse, mutect2, varscan2
- TCOF1 | c.2963G>A p.R988Q (on ENST00000377797 / NM_001135243.1; = p.R911Q on NM_000356.4) | Missense Mutation (SNP) | VAF 230/464 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs753946962; called by muse, mutect2, varscan2
- TENM3 | c.7309G>A p.E2437K | Missense Mutation (SNP) | VAF 158/362 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs1019400079, COSV69301857; called by muse, mutect2, varscan2
- TLX3 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 250/558 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766623983; called by muse, varscan2
- TRBC2 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 169/291 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782199893; called by muse, mutect2, varscan2
- TRIM49 | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61670608; called by muse, varscan2
- TRPC4 | c.2146C>T p.R716* (on ENST00000379705 / NM_016179.4; = p.R721* on NM_003306.3) | Nonsense Mutation (SNP) | VAF 113/235 reads (48%) | catalogued as COSV59009541; called by muse, mutect2, varscan2
- TTN | c.22551A>C p.E7517D (on ENST00000591111; = p.E6590D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/332 reads (50%) | PolyPhen benign (0); catalogued as COSV60416470; called by muse, mutect2, varscan2
- TYK2 | c.1579C>G p.R527G | Missense Mutation (SNP) | VAF 254/547 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs777266572, COSV53387075; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP28 | c.2846G>A p.R949Q | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757379676, COSV50183468, COSV99135648; called by muse, mutect2, varscan2
- USP29 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 108/244 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs372152335; called by muse, mutect2, varscan2
- WDR83 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1209959604, COSV52951505; called by muse, mutect2
- WIPI2 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 128/256 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs371973214; called by muse, mutect2, varscan2
- ZFHX3 | c.7822A>T p.T2608S | Missense Mutation (SNP) | VAF 172/347 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs111288031; called by muse, mutect2, varscan2
- ZFP1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 116/274 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs949971145; called by muse, mutect2, varscan2
- ZIC3 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 491/525 reads (94%) | SIFT tolerated (0.62); PolyPhen benign (0.17); catalogued as COSV99798870; called by muse, mutect2, varscan2
- ZNF285 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as rs1191167563; called by muse, mutect2
- ZNF324 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 313/672 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1461200112, COSV99543357; called by muse, mutect2, varscan2
- ABCB8 | c.2063G>A p.W688* (on ENST00000297504 / NM_001282291.2; = p.W671* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 121/300 reads (40%) | called by muse, mutect2, varscan2
- ACSL4 | c.1996G>A p.E666K (on ENST00000340800 / NM_022977.2; = p.E625K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL3 | c.2477A>G p.E826G (on ENST00000506720 / NM_001322402.2; = p.E758G on NM_015236.6) | Missense Mutation (SNP) | VAF 205/398 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AFF4 | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGBL4 | c.1371A>T p.K457N | Missense Mutation (SNP) | VAF 132/248 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP23 | c.4385C>T p.A1462V | Missense Mutation (SNP) | VAF 321/672 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB17 | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ASB18 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 246/488 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- BCORL1 | c.3811A>G p.T1271A | Missense Mutation (SNP) | VAF 412/412 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BMF | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- C2CD3 | c.5813A>G p.D1938G | Missense Mutation (SNP) | VAF 149/341 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CACNA1G | c.6502T>C p.S2168P | Missense Mutation (SNP) | VAF 127/599 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALN1 | c.131C>A p.A44D (on ENST00000329008 / NM_001017440.3; = p.A86D on NM_031468.4) | Missense Mutation (SNP) | VAF 137/329 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CAVIN1 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 16/518 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2
- CCDC168 | c.6143G>T p.R2048I | Missense Mutation (SNP) | VAF 155/330 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CCDC63 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 34/646 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC71 | c.1368A>G p.I456M | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CDH18 | c.2000del p.D667Afs*10 | Frame Shift Del (DEL) | VAF 130/343 reads (38%) | called by mutect2, pindel, varscan2
- CFAP47 | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 118/118 reads (100%) | called by muse, mutect2, varscan2
- CHD7 | c.5018A>G p.D1673G | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- CHSY3 | c.1358A>G p.N453S | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.065); called by muse, mutect2
- CLDN3 | c.364dup p.V122Gfs*189 | Frame Shift Ins (INS) | VAF 312/731 reads (43%) | called by mutect2, pindel, varscan2
- CNP | c.712T>G p.L238V | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CR1 | c.5782T>C p.Y1928H | Missense Mutation (SNP) | VAF 129/452 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CYLC1 | c.1175A>C p.K392T | Missense Mutation (SNP) | VAF 225/239 reads (94%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DCAF8L2 | c.316G>C p.V106L | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2
- DEPDC1 | c.1066A>G p.K356E | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMRTA1 | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 260/294 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.24); called by mutect2, varscan2
- DNAH6 | c.8017C>G p.L2673V | Missense Mutation (SNP) | VAF 120/216 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- DNAJC13 | c.2072A>C p.Y691S | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- E2F8 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EFR3B | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 28/710 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- ERVMER34-1 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- F2RL3 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 349/688 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FAM135B | c.2552A>T p.K851I | Missense Mutation (SNP) | VAF 181/741 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FRY | c.220T>G p.F74V | Missense Mutation (SNP) | VAF 156/313 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GABRB2 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GABRR2 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 138/406 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GFPT2 | c.1091T>G p.I364S | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GLYATL1B | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 176/362 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPC6 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2
- GPR135 | c.1284T>A p.S428R | Missense Mutation (SNP) | VAF 37/582 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- GPR149 | c.1216dup p.S406Kfs*6 | Frame Shift Ins (INS) | VAF 72/199 reads (36%) | called by mutect2, pindel, varscan2
- GPR25 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 638/863 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- GRIA2 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 111/245 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GRIA4 | c.1295A>C p.K432T | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- HERC6 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 178/419 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDH2 | c.123C>G p.D41E | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2
- IGFBP7 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 238/511 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL13RA2 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN2 | c.1725T>A p.D575E | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- KBTBD3 | c.1654A>C p.K552Q | Missense Mutation (SNP) | VAF 157/304 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM6B | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KDR | c.3347G>C p.C1116S | Missense Mutation (SNP) | VAF 138/294 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRBA | c.7205A>T p.E2402V | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LRRC7 | c.3908A>T p.K1303I (on ENST00000651989 / NM_001370785.2; = p.K1270I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/338 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); called by muse, mutect2
- MAP1B | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MED16 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 138/300 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MPDZ | c.1860A>C p.K620N | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYLK3 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 252/494 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYRFL | c.1991G>C p.S664T | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- NCDN | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 257/538 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- NCKAP5 | c.3302A>C p.K1101T | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2
- NDST1 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 231/446 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NLGN1 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 191/426 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- NOL9 | c.1085dup p.T363Hfs*18 | Frame Shift Ins (INS) | VAF 90/238 reads (38%) | called by mutect2, pindel, varscan2
- NR1D2 | c.1452C>G p.N484K | Missense Mutation (SNP) | VAF 175/330 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- NT5C1B | c.1612G>T p.A538S (on ENST00000359846 / NM_001199086.2; = p.A478S on NM_033253.4) | Missense Mutation (SNP) | VAF 203/427 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OGFRL1 | c.322-1G>A p.X108_splice | Splice Site (SNP) | VAF 108/182 reads (59%) | called by muse, mutect2, varscan2
- OR13C8 | c.815A>C p.N272T | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR2T29 | c.167A>C p.D56A | Missense Mutation (SNP) | VAF 184/452 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2
- OR2T5 | c.167A>C p.D56A | Missense Mutation (SNP) | VAF 285/877 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- OR8H2 | c.188del p.F63Sfs*21 | Frame Shift Del (DEL) | VAF 33/300 reads (11%) | called by mutect2, pindel, varscan2
- OR8K3 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDH15 | c.5699A>G p.Y1900C | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PEG3 | c.3106T>G p.F1036V | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by muse, mutect2
- PRPF6 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 81/329 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RAB14 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 181/235 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RABGAP1L | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RNF214 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTN3 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SERAC1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SIRT6 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 70/464 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLIRP | c.315A>C p.E105D | Missense Mutation (SNP) | VAF 146/290 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SLITRK3 | c.2712T>A p.Y904* | Nonsense Mutation (SNP) | VAF 228/419 reads (54%) | called by muse, mutect2, varscan2
- SPART | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 133/269 reads (49%) | called by muse, mutect2, varscan2
- SPECC1 | c.2384T>C p.V795A | Missense Mutation (SNP) | VAF 135/309 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRGAP1 | c.1843C>A p.H615N | Missense Mutation (SNP) | VAF 133/425 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ST8SIA4 | c.231G>C p.L77F | Missense Mutation (SNP) | VAF 100/193 reads (52%) | PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- STAM2 | c.95T>G p.I32R | Missense Mutation (SNP) | VAF 139/261 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNM | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 44/786 reads (6%) | called by muse, mutect2
- TMTC1 | c.757A>G p.S253G (on ENST00000539277 / NM_001193451.2; = p.S145G on NM_175861.3) | Missense Mutation (SNP) | VAF 30/539 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- TMTC3 | c.2689A>G p.R897G | Missense Mutation (SNP) | VAF 15/381 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TOPAZ1 | c.4607T>G p.F1536C | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TRIM67 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 92/1291 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- TTC22 | c.359A>T p.E120V | Missense Mutation (SNP) | VAF 348/684 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- USF1 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 127/440 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- VCAN | c.5897A>G p.D1966G | Missense Mutation (SNP) | VAF 169/357 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- WNK2 | c.2146C>G p.P716A | Missense Mutation (SNP) | VAF 80/769 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WWP1 | c.2063G>C p.S688T | Missense Mutation (SNP) | VAF 114/454 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF181 | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF345 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 123/291 reads (42%) | called by muse, mutect2, varscan2
- ZNF461 | c.1317A>C p.K439N | Missense Mutation (SNP) | VAF 211/418 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF595 | c.1244dup p.R416Efs*19 | Frame Shift Ins (INS) | VAF 142/349 reads (41%) | called by mutect2, pindel, varscan2
- ZNF611 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF735 | c.1185T>G p.S395R | Missense Mutation (SNP) | VAF 109/242 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZRANB2 | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ADAMTS15 | c.2142C>T p.R714= | Silent (SNP) | VAF 155/312 reads (50%) | catalogued as rs375820237; called by muse, mutect2, varscan2
- ADAMTS20 | c.4575T>C p.C1525= | Silent (SNP) | VAF 176/564 reads (31%) | catalogued as rs751873705; called by muse, mutect2, varscan2
- ALDH16A1 | c.1167C>T p.P389= | Silent (SNP) | VAF 184/417 reads (44%) | catalogued as rs1472773273; called by muse, mutect2, varscan2
- ALPP | c.1560T>C p.P520= | Silent (SNP) | VAF 285/636 reads (45%) | catalogued as rs759869887; called by muse, mutect2, varscan2
- ASXL1 | c.2559G>A p.P853= | Silent (SNP) | VAF 144/444 reads (32%) | catalogued as rs777169553; called by muse, mutect2, varscan2
- ATP10A | c.6G>A p.E2= | Silent (SNP) | VAF 117/247 reads (47%) | catalogued as rs1224412037; called by muse, mutect2, varscan2
- BACE1 | c.228C>T p.Y76= | Silent (SNP) | VAF 38/500 reads (8%) | called by muse, mutect2
- BCL6B | c.1305C>T p.T435= | Silent (SNP) | VAF 193/395 reads (49%) | catalogued as rs539445999; called by muse, mutect2, varscan2
- BMP3 | c.1362G>A p.K454= | Silent (SNP) | VAF 118/248 reads (48%) | catalogued as COSV51082474; called by muse, mutect2, varscan2
- C11orf96 | c.1110G>A p.P370= (on ENST00000339446; = p.P57= on NM_001145033.2) | Silent (SNP) | VAF 203/449 reads (45%) | called by muse, mutect2, varscan2
- CCDC169 | c.195A>G p.Q65= | Silent (SNP) | VAF 109/242 reads (45%) | catalogued as rs1379416799; called by muse, mutect2, varscan2
- CCR1 | c.255C>T p.F85= | Silent (SNP) | VAF 125/271 reads (46%) | called by muse, mutect2, varscan2
- CD1C | c.732G>A p.Q244= | Silent (SNP) | VAF 22/740 reads (3%) | catalogued as COSV63807090; called by muse, mutect2
- CD300C | c.615G>T p.V205= | Silent (SNP) | VAF 144/334 reads (43%) | catalogued as COSV58170096; called by muse, mutect2, varscan2
- CDH18 | c.1137A>G p.E379= | Silent (SNP) | VAF 22/422 reads (5%) | called by muse, mutect2
- CLGN | c.1191C>T p.F397= | Silent (SNP) | VAF 104/211 reads (49%) | catalogued as rs76550209, COSV57773825; called by muse, mutect2, varscan2
- CTNNA3 | c.1911T>C p.S637= | Silent (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- DDX60 | c.4746A>G p.G1582= | Silent (SNP) | VAF 140/341 reads (41%) | called by muse, mutect2, varscan2
- DMD | c.7461T>C p.S2487= | Silent (SNP) | VAF 80/307 reads (26%) | called by muse, mutect2, varscan2
- DMKN | c.1335G>A p.K445= | Silent (SNP) | VAF 146/353 reads (41%) | catalogued as rs754204084; called by muse, mutect2, varscan2
- EPHA6 | c.2367A>C p.L789= (on ENST00000389672 / NM_001080448.3; = p.L181= on NM_173655.4) | Silent (SNP) | VAF 118/233 reads (51%) | called by muse, mutect2, varscan2
- FRMD7 | c.1422T>G p.T474= | Silent (SNP) | VAF 120/431 reads (28%) | catalogued as COSV100048554; called by muse, mutect2, varscan2
- GARNL3 | c.2217A>G p.Q739= | Silent (SNP) | VAF 250/342 reads (73%) | catalogued as rs62579716, COSV100149872; called by muse, mutect2, varscan2
- GRIK4 | c.570C>T p.S190= | Silent (SNP) | VAF 227/435 reads (52%) | catalogued as rs767558643; called by muse, mutect2, varscan2
- GRM6 | c.222C>T p.Y74= | Silent (SNP) | VAF 264/559 reads (47%) | catalogued as rs778393434, COSV51435478; called by muse, mutect2, varscan2
- HHIPL1 | c.2163C>T p.A721= | Silent (SNP) | VAF 333/698 reads (48%) | catalogued as rs1476558749; called by muse, mutect2, varscan2
- HPX | c.1074C>T p.D358= | Silent (SNP) | VAF 131/346 reads (38%) | called by muse, mutect2, varscan2
- IL20 | c.150G>T p.R50= | Silent (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- IQCJ-SCHIP1 | c.813C>T p.R271= (on ENST00000485419 / NM_001197113.1; = p.R195= on NM_014575.3) | Silent (SNP) | VAF 249/484 reads (51%) | catalogued as rs1376277517; called by muse, mutect2, varscan2
- IRS4 | c.2199T>C p.S733= | Silent (SNP) | VAF 35/405 reads (9%) | called by muse, mutect2
- IRS4 | c.381T>C p.A127= | Silent (SNP) | VAF 16/408 reads (4%) | called by muse, mutect2
- IRX1 | c.657C>T p.D219= | Silent (SNP) | VAF 226/493 reads (46%) | catalogued as rs757711798, COSV57359086; called by muse, mutect2, varscan2
- IRX2 | c.1350C>T p.Y450= | Silent (SNP) | VAF 139/315 reads (44%) | called by muse, mutect2, varscan2
- KCNQ3 | c.2313G>A p.S771= | Silent (SNP) | VAF 234/932 reads (25%) | catalogued as rs774793856; called by muse, mutect2, varscan2
- KIF2B | c.1542T>C p.T514= | Silent (SNP) | VAF 18/426 reads (4%) | catalogued as COSV52131834, COSV99276541; called by muse, mutect2
- KIRREL3 | c.2073C>T p.Y691= | Silent (SNP) | VAF 225/463 reads (49%) | catalogued as rs776552881; called by muse, mutect2, varscan2
- KMT2A | c.4308C>T p.L1436= | Silent (SNP) | VAF 25/262 reads (10%) | called by muse, mutect2
- KMT2A | c.11337C>T p.N3779= | Silent (SNP) | VAF 121/251 reads (48%) | called by muse, mutect2, varscan2
- KRT28 | c.276T>C p.N92= | Silent (SNP) | VAF 14/490 reads (3%) | called by muse, mutect2
- LRRC7 | c.3906T>G p.G1302= (on ENST00000651989 / NM_001370785.2; = p.G1269= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 149/333 reads (45%) | called by muse, mutect2
- MAGEC1 | c.1911A>G p.P637= | Silent (SNP) | VAF 390/390 reads (100%) | catalogued as COSV99596619; called by muse, mutect2, varscan2
- MAT1A | c.993C>A p.S331= | Silent (SNP) | VAF 121/275 reads (44%) | catalogued as COSV64746993; called by muse, mutect2, varscan2
- MUC4 | c.6588C>T p.T2196= | Silent (SNP) | VAF 268/1926 reads (14%) | catalogued as rs775918034; called by muse, mutect2, varscan2
- MUL1 | c.186C>T p.C62= | Silent (SNP) | VAF 93/204 reads (46%) | catalogued as rs747243113, COSV51641876; called by muse, mutect2, varscan2
- NLRP10 | c.1248A>G p.L416= | Silent (SNP) | VAF 38/588 reads (6%) | catalogued as rs767164554; called by muse, mutect2
- NLRP7 | c.444C>T p.D148= | Silent (SNP) | VAF 241/533 reads (45%) | catalogued as rs781097722, COSV60171380; called by muse, mutect2, varscan2
- NRG2 | c.1797C>T p.P599= | Silent (SNP) | VAF 20/506 reads (4%) | called by muse, mutect2
- NRXN3 | c.1629G>A p.P543= (on ENST00000557594 / NM_001272020.2; = p.P967= on NM_004796.6) | Silent (SNP) | VAF 168/339 reads (50%) | catalogued as rs1254494576, COSV55313998, COSV55324090; called by muse, varscan2
- OR4C13 | c.756C>T p.C252= | Silent (SNP) | VAF 46/333 reads (14%) | catalogued as rs782410077; called by muse, mutect2, varscan2
- OR5D14 | c.471C>A p.G157= | Silent (SNP) | VAF 188/375 reads (50%) | called by muse, mutect2, varscan2
- PCDH10 | c.540C>T p.F180= | Silent (SNP) | VAF 198/386 reads (51%) | catalogued as rs1482690505, COSV52106545, COSV99993471; called by muse, mutect2, varscan2
- PCDH17 | c.1536G>C p.L512= | Silent (SNP) | VAF 170/371 reads (46%) | called by muse, mutect2, varscan2
- PCDH7 | c.993C>T p.R331= | Silent (SNP) | VAF 239/521 reads (46%) | catalogued as COSV62337614; called by muse, mutect2, varscan2
- PNMA8B | c.1665C>T p.S555= | Silent (SNP) | VAF 180/413 reads (44%) | catalogued as COSV100885367; called by muse, mutect2, varscan2
- POU3F3 | c.861C>T p.H287= | Silent (SNP) | VAF 366/743 reads (49%) | catalogued as rs1228263823, COSV63721969; called by muse, varscan2
- RYR2 | c.663T>C p.S221= | Silent (SNP) | VAF 34/558 reads (6%) | called by muse, mutect2
- SAGE1 | c.1554T>C p.G518= | Silent (SNP) | VAF 206/206 reads (100%) | called by muse, mutect2, varscan2
- SERPINA3 | c.957G>A p.S319= | Silent (SNP) | VAF 148/321 reads (46%) | catalogued as rs1227830345, COSV67586962; called by muse, mutect2, varscan2
- SHANK3 | c.4320C>T p.H1440= | Silent (SNP) | VAF 326/632 reads (52%) | catalogued as rs760393773; called by muse, mutect2, varscan2
- SHISAL1 | c.123C>T p.Y41= | Silent (SNP) | VAF 167/303 reads (55%) | catalogued as COSV101152141; called by muse, mutect2, varscan2
- SLC25A2 | c.171A>G p.Q57= | Silent (SNP) | VAF 38/532 reads (7%) | called by muse, mutect2
- SLC39A10 | c.1428G>C p.G476= | Silent (SNP) | VAF 152/277 reads (55%) | called by muse, mutect2, varscan2
- SMARCA2 | c.801G>A p.P267= | Silent (SNP) | VAF 190/225 reads (84%) | called by muse, mutect2, varscan2
- SOX10 | c.78G>A p.G26= | Silent (SNP) | VAF 270/604 reads (45%) | called by muse, varscan2
- SPATA31D1 | c.3360T>C p.A1120= | Silent (SNP) | VAF 34/485 reads (7%) | catalogued as COSV61193351; called by muse, mutect2
- TLL1 | c.873T>C p.Y291= | Silent (SNP) | VAF 16/262 reads (6%) | catalogued as rs1474397099; called by muse, mutect2
- TMEM198 | c.978C>T p.T326= | Silent (SNP) | VAF 165/385 reads (43%) | catalogued as rs780003867; called by muse, mutect2, varscan2
- TP63 | c.1854G>T p.R618= | Silent (SNP) | VAF 32/548 reads (6%) | catalogued as COSV99288120; called by muse, mutect2
- TPH2 | c.735G>A p.L245= | Silent (SNP) | VAF 186/513 reads (36%) | called by muse, mutect2, varscan2
- VSX2 | c.42C>T p.S14= | Silent (SNP) | VAF 184/377 reads (49%) | catalogued as rs1228326703; called by muse, mutect2, varscan2
- WDR72 | c.1681A>C p.R561= | Silent (SNP) | VAF 67/333 reads (20%) | called by muse, mutect2, varscan2
- XKR7 | c.897C>T p.A299= | Silent (SNP) | VAF 271/798 reads (34%) | catalogued as rs764910227; called by muse, mutect2, varscan2
- ZNF777 | c.1626C>T p.G542= | Silent (SNP) | VAF 420/753 reads (56%) | catalogued as rs367681984; called by muse, mutect2, varscan2
- AGAP14P | n.562G>A | RNA (SNP) | VAF 34/516 reads (7%) | called by muse, mutect2
- ANKRD20A8P | n.1456A>G | RNA (SNP) | VAF 137/419 reads (33%) | called by muse, mutect2, varscan2
- ATXN8OS | n.499+1066C>T | Intron (SNP) | VAF 116/242 reads (48%) | catalogued as rs567701973; called by muse, mutect2, varscan2
- C19orf25 | c.131-929C>T | Intron (SNP) | VAF 16/414 reads (4%) | catalogued as rs1349646244; called by muse, mutect2
- CSMD2 | c.67+712C>T | Intron (SNP) | VAF 42/584 reads (7%) | called by muse, mutect2
- DAPL1 | c.226-8792G>A | Intron (SNP) | VAF 119/235 reads (51%) | catalogued as rs1237503774; called by muse, mutect2, varscan2
- DUSP13 | c.*486G>A | 3'UTR (SNP) | VAF 28/249 reads (11%) | catalogued as rs768260579, COSV100403768; called by muse, mutect2, varscan2
- MAPK8 | c.688+358A>G | Intron (SNP) | VAF 93/184 reads (51%) | called by muse, mutect2, varscan2
- MLIP | c.613-10836G>A | Intron (SNP) | VAF 111/326 reads (34%) | called by muse, mutect2, varscan2
- OR5K2 | chr3:98501459 G>A | 3'Flank (SNP) | VAF 124/295 reads (42%) | catalogued as rs1240350676; called by muse, mutect2, varscan2
- SLC12A4 | c.116-412G>A | Intron (SNP) | VAF 172/358 reads (48%) | called by muse, mutect2, varscan2
- ZNF812P | n.1515T>C | RNA (SNP) | VAF 139/306 reads (45%) | catalogued as rs1265067408; called by muse, mutect2, varscan2
